Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A2LO, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A2LO-01A (Primary Tumor).

ICD-O-3
carcinoma, infiltrating lobular, NOS 8520/3
Site: breast, NOS C50.9 *per* 8/18/11

Final Diagnosis

- A. Breast, left, simple mastectomy: Infiltrating lobular carcinoma, Nottingham grade I (of III) [tubules 3/3, nuclei 1/3, mitoses 1/3; Nottingham score 5/9] is identified forming a mass (4.8 x 2.7 x 1.9 cm) located in the lower outer quadrant of the breast. Biopsy site changes are present. The tumor does not involve the nipple, overlying skin, or underlying chest wall. Lobular carcinoma in situ is also present. All surgical resection margins, including the deep margin, are negative for tumor (minimum tumor free margin, 0.3 cm, deep margin and 0.5 cm, superficial margin). With available surgical material, the AJCC staging is pT2NXMX (see comment).
- B. Breast, right, simple mastectomy: Benign nonproliferative breast parenchyma.
- C. Lymph nodes, left axillary, lymphadenectomy: Multiple (14) lymph nodes are negative for tumor.
- D. Lymph nodes, left lowest axillary, lymphadenectomy: Fibroadipose tissue, negative for tumor. No lymphoid tissue identified.

WJ / *8/18/11*

Source: NCI Genomic Data Commons file e85436a0-a822-44ba-90f4-819410d95e5b (TCGA-AR-A2LO.E5B6771D-450A-49AD-AEBC-7FC056BFCDBE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).